Somatic mutation profile of tumor specimen TARGET-30-PASCEW-09A (aliquot TARGET-30-PASCEW-09A-01D) from TARGET case TARGET-30-PASCEW, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peripheral nerves and autonomic nervous system of abdomen; Age at diagnosis: 4.0 years (1,477 days).
Specimen TARGET-30-PASCEW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77e4f29a-9828-4e8c-953a-f7a34361a54d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASCEW-10A (Blood Derived Normal), aliquot TARGET-30-PASCEW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1d1fd4a-e612-47bb-949e-d490a5deb6b3

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K4 | c.2439C>T p.S813= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV62332773; called by muse, mutect2, varscan2
